Somatic mutation profile of tumor specimen TCGA-BA-A4II-01A (aliquot TCGA-BA-A4II-01A-11D-A25Y-08) from TCGA case TCGA-BA-A4II, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 46.6 years (17,011 days).
Specimen TCGA-BA-A4II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cc36120-ce04-4e93-8e5d-2072f28a99ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A4II-10A (Blood Derived Normal), aliquot TCGA-BA-A4II-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5a86362-e1d9-4fec-9c57-65d22784a78a

The open-access MAF lists 107 somatic variants for this specimen: 76 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 30, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2115G>T p.L705F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as COSV100750590; called by muse, mutect2, varscan2
- ADGRA2 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV100177617, COSV100177671; called by muse, mutect2, varscan2
- ADGRA2 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139221615; called by muse, mutect2, varscan2
- ATP10A | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790979; called by muse, mutect2, varscan2
- B3GNT7 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs769579473, COSV99805850; called by muse, mutect2, varscan2
- BMP6 | c.1196G>T p.S399I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.342); catalogued as COSV99306441; called by muse, mutect2
- BRINP3 | c.282A>T p.R94S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1558142627, COSV100818444; called by muse, mutect2, varscan2
- BTN3A3 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.121); catalogued as COSV99764784; called by muse, mutect2, varscan2
- C11orf87 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100535692; called by muse, mutect2, varscan2
- C6 | c.1010T>A p.V337D | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV99666647, COSV99667880; called by muse, mutect2, varscan2
- CCDC6 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99569221; called by muse, mutect2, varscan2
- CHML | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 41/203 reads (20%) | catalogued as COSV100087124; called by muse, mutect2, varscan2
- CNTN4 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as rs1372774754, COSV100638910; called by muse, mutect2
- DENND1B | c.1146del p.K382Nfs*11 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as COSV52462576; called by mutect2, pindel, varscan2
- DOCK3 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99809761; called by muse, mutect2, varscan2
- DPYS | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1423082168, COSV100679337; called by muse, mutect2, varscan2
- DUOX2 | c.1235-1G>T p.X412_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101199605; called by muse, mutect2, varscan2
- EEF1A2 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV53207770; called by muse, mutect2, varscan2
- ENPP3 | c.2220A>T p.R740S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV100716810; called by muse, mutect2, varscan2
- EPB41L3 | c.3237G>T p.E1079D | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59448726, COSV59449179; called by muse, mutect2, varscan2
- ERI1 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1563312851, COSV99141274; called by muse, mutect2, varscan2
- ERICH3 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100443619; called by muse, mutect2, varscan2
- FBXL17 | c.1851G>T p.M617I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62855793; called by muse, mutect2, varscan2
- FRYL | c.2591G>C p.W864S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99976096, COSV99977101; called by muse, mutect2, varscan2
- GAMT | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758217156, COSV99282643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNG13 | c.32_35del p.K11Rfs*24 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs746112646; called by pindel, varscan2
- GOLGB1 | c.8859G>A p.R2953= | Splice Region (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100510411; called by muse, mutect2, varscan2
- HCN1 | c.947A>C p.Q316P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100299020; called by muse, mutect2, varscan2
- HSD17B8 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV100761725, COSV63002393, COSV63003012; called by muse, mutect2
- ID2 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99301054; called by muse, mutect2
- IGHG2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764823624; called by muse, mutect2, varscan2
- IRF2BP2 | c.1171A>G p.M391V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs776982084, COSV100784260; called by muse, mutect2
- KANSL1L | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99910233; called by muse, mutect2
- KCNT2 | c.2849C>A p.S950Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99652049; called by muse, mutect2, varscan2
- LYSMD3 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100270312; called by muse, mutect2, varscan2
- MAP3K19 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100208186; called by muse, mutect2
- MAPK8IP3 | c.1536G>A p.S512= | Splice Region (SNP) | VAF 18/107 reads (17%) | catalogued as rs753288745, COSV99167745; called by muse, mutect2, varscan2
- MRPS5 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV99720711; called by muse, mutect2, varscan2
- MTMR8 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100878333; called by muse, mutect2, varscan2
- NLRP3 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV100275435; called by muse, mutect2, varscan2
- OR8K5 | c.638T>A p.I213K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as COSV100537162; called by muse, mutect2, varscan2
- PARD3B | c.3542G>T p.R1181L (on ENST00000406610 / NM_001302769.2; = p.R1112L on NM_057177.7) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV100592411; called by muse, mutect2, varscan2
- PCDHGA2 | c.2424+2T>C p.X808_splice | Splice Site (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99532787; called by muse, mutect2
- PDE8B | c.1727T>A p.L576Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99366278; called by muse, mutect2
- PLPPR4 | c.409-1G>T p.X137_splice | Splice Site (SNP) | VAF 16/226 reads (7%) | catalogued as COSV100926722; called by muse, mutect2
- PPP5C | c.1245G>T p.L415F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99181076; called by muse, mutect2, varscan2
- QPRT | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99568924; called by muse, mutect2
- RNF169 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100213251; called by muse, mutect2
- S1PR3 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100822479; called by muse, mutect2
- SEC22A | c.456A>C p.Q152H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100006842; called by muse, mutect2, varscan2
- SLC35B4 | c.357C>G p.F119L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101043021; called by muse, mutect2, varscan2
- SLC36A2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs767426391, COSV58862677; called by muse, mutect2, varscan2
- SLC4A11 | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs763849883, COSV101195909; called by muse, mutect2, varscan2
- SUGP1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99894706; called by muse, mutect2, varscan2
- SV2A | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.773); catalogued as rs782742097, COSV64964535; called by mutect2, varscan2
- TMEM132D | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV67159375; called by muse, mutect2, varscan2
- TMEM132D | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372764040; called by muse, mutect2, varscan2
- TNFRSF21 | c.1760G>C p.R587P | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57279868, COSV99729235; called by muse, mutect2, varscan2
- TNIK | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1419784217, COSV99455573; called by muse, mutect2
- TRDN | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs773142604, COSV100521071; called by muse, mutect2, varscan2
- TRMT61B | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1331246071; called by muse, mutect2
- UBR2 | c.3535A>G p.R1179G | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100867382; called by muse, mutect2, varscan2
- VASP | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1416879210, COSV55608815; called by muse, mutect2
- XPO4 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV99688149; called by muse, mutect2, varscan2
- ZIC2 | c.1594G>C p.V532L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV100891764; called by muse, mutect2
- ZNF154 | c.459A>T p.R153S | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101377459; called by muse, mutect2, varscan2
- ZNF280B | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1188372286, COSV100840205, COSV64529290; called by muse, mutect2, varscan2
- ZNF30 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100340385; called by muse, mutect2, varscan2
- ZNF318 | c.1931_1966del p.H644_D655del | In Frame Del (DEL) | VAF 26/178 reads (15%) | catalogued as rs774173110; called by muse*, mutect2
- ZNF341 | c.2356G>A p.E786K (on ENST00000375200 / NM_001282935.1; = p.E779K on NM_032819.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs751373005, COSV100677760, COSV100678075; called by muse, mutect2, varscan2
- ZNF43 | c.1209T>A p.C403* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100731717; called by muse, mutect2, varscan2
- ZNF813 | c.675T>A p.N225K | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV101124707; called by muse, mutect2, varscan2
- MBOAT7 | c.1046dup p.M349Ifs*60 | Frame Shift Ins (INS) | VAF 7/55 reads (13%) | called by mutect2, varscan2
- NONO | c.315_318del p.H106Rfs*15 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by pindel, varscan2
- ZNF292 | c.1924dup p.S642Ffs*8 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- AHNAK | c.1323A>G p.V441= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV99946013; called by muse, mutect2, varscan2
- ANG | c.366G>A p.A122= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs369214577, COSV59012444; called by muse, mutect2, varscan2
- CARMIL1 | c.3366G>C p.R1122= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100277127; called by muse, mutect2, varscan2
- CHEK2 | c.69C>A p.G23= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs865997083, COSV100101175; called by muse, mutect2, varscan2
- EEF2 | c.2013C>T p.Y671= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100500612; called by mutect2, varscan2
- GPR161 | c.48C>A p.L16= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99606316; called by muse, mutect2, varscan2
- HR | c.3543C>T p.A1181= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs372917956; called by muse, mutect2, varscan2
- JAKMIP1 | c.1125G>A p.A375= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs150623866; called by mutect2, varscan2
- KRT6A | c.1662C>T p.T554= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV100416774, COSV58104115; called by muse, varscan2
- LRRC1 | c.399T>C p.L133= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100905985; called by muse, mutect2, varscan2
- MED14 | c.2445C>T p.T815= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100247365; called by muse, mutect2, varscan2
- NRXN2 | c.2988C>G p.V996= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99632883; called by muse, mutect2
- OPN5 | c.444C>T p.H148= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs759743748, COSV55247486; called by muse, mutect2
- PABPC3 | c.138G>A p.L46= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV55798395, COSV99879200; called by muse, mutect2
- PCDHB12 | c.1878C>T p.T626= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99506886, COSV99507591; called by muse, mutect2, varscan2
- PCDHGA5 | c.1533C>T p.T511= | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as COSV54003381, COSV54046314; called by muse, mutect2, varscan2
- PDZRN4 | c.2247G>T p.P749= (on ENST00000402685 / NM_001164595.2; = p.P491= on NM_013377.4) | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100113832; called by muse, mutect2, varscan2
- PLEKHA6 | c.615C>T p.A205= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55339427, COSV99691483, COSV99691662; called by muse, mutect2, varscan2
- PTPRB | c.4515G>A p.Q1505= | Silent (SNP) | VAF 35/209 reads (17%) | catalogued as COSV99716232; called by muse, mutect2, varscan2
- RAB7A | c.589C>A p.R197= | Silent (SNP) | VAF 38/272 reads (14%) | catalogued as COSV99413909; called by muse, mutect2, varscan2
- RFT1 | c.1170T>C p.C390= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99965354; called by muse, mutect2, varscan2
- RUSC2 | c.198A>G p.L66= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs572264282, COSV100770616; called by muse, mutect2, varscan2
- SLC25A42 | c.549G>A p.L183= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs780933553, COSV59381644; called by muse, mutect2, varscan2
- STK32B | c.183G>A p.E61= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99284444; called by muse, mutect2, varscan2
- TENM1 | c.6876A>G p.T2292= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV100949300; called by muse, mutect2, varscan2
- THSD7B | c.2796A>G p.G932= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs752781432, COSV99745789; called by muse, mutect2, varscan2
- TNR | c.693C>T p.S231= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs775081401, COSV54874573; called by muse, mutect2, varscan2
- TRPA1 | c.1377C>A p.I459= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100083418, COSV51555606; called by muse, mutect2, varscan2
- TSPOAP1 | c.4785C>G p.P1595= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV52104070, COSV99270284; called by muse, mutect2, varscan2
- VWA3B | c.2328G>T p.L776= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101345957; called by muse, mutect2, varscan2
- AFDN | chr6:167825913 T>C | 5'Flank (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
